Somatic mutation profile of tumor specimen TCGA-73-7499-01A (aliquot TCGA-73-7499-01A-11D-2184-08) from TCGA case TCGA-73-7499, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 81.3 years (29,683 days).
Specimen TCGA-73-7499-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4d7bedd-5236-4302-876e-485fc1e8b185.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-73-7499-10A (Blood Derived Normal), aliquot TCGA-73-7499-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4043db72-f008-44d3-b59d-660a2272e4b8

The open-access MAF lists 66 somatic variants for this specimen: 55 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 50, Silent 11, Nonsense Mutation 3, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALMS1 | c.2929G>A p.E977K | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52504029; called by muse, mutect2, varscan2
- BCL3 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 28/424 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as COSV51233838; called by muse, mutect2
- C10orf90 | c.422C>G p.T141S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as COSV52950215; called by muse, mutect2, varscan2
- C1orf116 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs771577563, COSV63943790; called by muse, mutect2, varscan2
- CAMK2B | c.1055T>A p.V352D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as COSV51657821; called by muse, mutect2, varscan2
- CEP85L | c.1147C>G p.Q383E | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV63820933; called by muse, mutect2, varscan2
- CFAP44 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV55609136; called by muse, mutect2
- CHD6 | c.5752G>C p.E1918Q | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.123); catalogued as COSV64688648; called by muse, mutect2
- CYP4A11 | c.167C>A p.S56Y | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV60222350; called by muse, mutect2, varscan2
- CYP4F12 | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV61172614; called by muse, mutect2
- DMXL2 | c.3704C>A p.S1235Y | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV51841530, COSV51841824; called by muse, mutect2
- EMC2 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as rs773459838, COSV55208114; called by muse, mutect2, varscan2
- EREG | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55260779; called by muse, mutect2, varscan2
- EZH1 | c.2074G>T p.V692L | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs775259824, COSV52848281; called by muse, mutect2, varscan2
- IL31RA | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 17/124 reads (14%) | catalogued as COSV51679108; called by muse, mutect2, varscan2
- INSL5 | c.393G>C p.L131F | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1488253098, COSV58787966; called by muse, mutect2, varscan2
- ITGA5 | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs143754928, COSV53215878; called by muse, mutect2, varscan2
- KCNB2 | c.1204T>C p.C402R | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV73049125; called by muse, mutect2, varscan2
- KIAA0100 | c.4636T>A p.F1546I | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.089); catalogued as COSV66490920; called by muse, mutect2, varscan2
- MAGEA12 | c.871C>G p.L291V | Missense Mutation (SNP) | VAF 29/415 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1556833634, COSV63294251; called by muse, mutect2
- MAN1A2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV62976483; called by muse, mutect2, varscan2
- MAPK6 | c.1613G>C p.S538T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV55929006; called by muse, mutect2, varscan2
- MED1 | c.2666G>C p.S889T | Missense Mutation (SNP) | VAF 52/282 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV56122695; called by muse, mutect2, varscan2
- MERTK | c.2165G>T p.R722L | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54925189, COSV54925205; called by muse, mutect2, varscan2
- MFN2 | c.2203A>C p.R735= | Splice Region (SNP) | VAF 4/42 reads (10%) | catalogued as rs755588768, COSV52420793; called by mutect2, varscan2
- NEB | c.18403G>A p.D6135N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV50828308; called by muse, mutect2, varscan2
- NFAT5 | c.1274C>G p.S425C | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV63025473; called by muse, mutect2, varscan2
- NOS1 | c.2688C>G p.H896Q | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.874); catalogued as COSV100500391; called by muse, mutect2, varscan2
- NUP43 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs778155818, COSV61190691; called by muse, mutect2, varscan2
- OR1K1 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.774); catalogued as rs138952318; called by muse, mutect2, varscan2
- OR2G2 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.692); catalogued as COSV60739570; called by muse, mutect2, varscan2
- PAPPA | c.1327C>A p.L443M | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.291); catalogued as COSV60278317; called by muse, mutect2, varscan2
- PBX3 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100655294, COSV60730771; called by muse, mutect2, varscan2
- PCDHB6 | c.870C>A p.F290L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as COSV50689807, COSV50690666; called by muse, mutect2, varscan2
- PCNX2 | c.3482T>A p.L1161H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50783999; called by muse, mutect2
- PDPN | c.457A>G p.M153V (on ENST00000621990; = p.M229V on NM_006474.4) | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53846583; called by muse, mutect2, varscan2
- PGAM4 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV58443308; called by muse, mutect2, varscan2
- PIK3CA | c.369G>T p.M123I | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.099); catalogued as COSV99836374; called by muse, mutect2, varscan2
- PIK3CA | c.370C>G p.P124A | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV55888156, COSV56031835, COSV99836380; called by muse, mutect2, varscan2
- PLD1 | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100577663, COSV60565858; called by muse, mutect2, varscan2
- PRDM15 | c.2425G>A p.V809I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs746926665, COSV54149574; called by muse, mutect2, varscan2
- PROS1 | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV67774118; called by muse, mutect2, varscan2
- PTGER4 | c.1450T>G p.S484A | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.049); catalogued as COSV56720172; called by muse, mutect2, varscan2
- RYR2 | c.6431G>A p.R2144H | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as rs1243083109, COSV63666184; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCRIB | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 17/363 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.918); catalogued as COSV57582850; called by muse, mutect2
- SLC39A11 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs1443357365, COSV55282509; called by muse, mutect2, varscan2
- SNX13 | c.2491G>C p.A831P | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV68063993; called by muse, mutect2, varscan2
- SPTA1 | c.2671C>T p.R891* | Nonsense Mutation (SNP) | VAF 68/289 reads (24%) | catalogued as rs755630903, CM148356, COSV63749670; called by muse, mutect2, varscan2
- UBAP2 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.621); catalogued as COSV62545374; called by muse, mutect2
- WAS | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100939471; called by muse, mutect2, varscan2
- WDR49 | c.506G>A p.G169E (on ENST00000308378 / NM_001366158.1; = p.G510E on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.155); catalogued as COSV57703268; called by muse, mutect2, varscan2
- ZNF578 | c.1312C>A p.H438N | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV101405039, COSV69736600; called by muse, mutect2
- ZNF615 | c.1634G>A p.C545Y | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65032195; called by muse, mutect2
- WDR45B | c.742_743del p.S248Qfs*12 | Frame Shift Del (DEL) | VAF 29/99 reads (29%) | called by mutect2, pindel*, varscan2*
- ASTN2 | c.1053G>C p.L351= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as COSV57755014; called by muse, mutect2, varscan2
- CDHR2 | c.3932G>A p.*1311= | Silent (SNP) | VAF 8/204 reads (4%) | catalogued as COSV56135192; called by muse, mutect2
- CFAP100 | c.969A>G p.T323= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV61502487; called by muse, mutect2
- DACT1 | c.2139C>T p.Y713= | Silent (SNP) | VAF 55/99 reads (56%) | catalogued as rs778935261, COSV60019654; called by muse, mutect2, varscan2
- DHX38 | c.792C>T p.D264= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV51696542; called by muse, mutect2, varscan2
- DOP1B | c.5295T>C p.F1765= | Silent (SNP) | VAF 79/260 reads (30%) | catalogued as COSV67692301; called by muse, mutect2, varscan2
- HRG | c.144C>T p.F48= | Silent (SNP) | VAF 8/199 reads (4%) | catalogued as COSV51644235; called by muse, mutect2
- PPFIA2 | c.2823A>G p.R941= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV61022270; called by muse, mutect2, varscan2
- SCN11A | c.3898C>T p.L1300= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV56566594; called by muse, mutect2, varscan2
- TADA2A | c.933G>A p.E311= | Silent (SNP) | VAF 30/196 reads (15%) | called by muse, mutect2, varscan2
- TBC1D25 | c.1842G>A p.G614= | Silent (SNP) | VAF 12/151 reads (8%) | catalogued as COSV65123302; called by muse, mutect2
